Somatic mutation profile of tumor specimen BLGSP-71-06-00157-01A (aliquot BLGSP-71-06-00157-01A-01D-A690-33) from CGCI case BLGSP-71-06-00157, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 5.9 years (2,154 days).
Specimen BLGSP-71-06-00157-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90387fbb-b5fe-4d36-b6aa-ca0717e552cc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00157-99A (Granulocytes), aliquot BLGSP-71-06-00157-99A-01W-A690-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1148572b-1990-4e9b-9a03-fc0604b4031d

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Splice Site 2, Intron 1, Silent 1, RNA 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1579C>T p.R527C (on ENST00000399959; = p.R528C on NM_001356.5) | Missense Mutation (SNP) | VAF 272/728 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1064795323, COSV67863221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 86/324 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1057519952, COSV69041759; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXO11 | c.2084-2A>G p.X695_splice (on ENST00000403359 / NM_001190274.2; = p.X611_splice on NM_025133.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 110/282 reads (39%) | catalogued as COSV52276686; called by muse, mutect2, varscan2
- MYC | c.524G>A p.S175N (on ENST00000377970; = p.S190N on NM_002467.6) | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as COSV52367488, COSV99419768; called by muse, mutect2, varscan2
- GNA13 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | called by muse, varscan2
- USP7 | c.383+1G>A p.X128_splice | Splice Site (SNP) | VAF 100/241 reads (41%) | called by mutect2, varscan2
- FNDC3B | c.312G>A p.Q104= | Silent (SNP) | VAF 176/453 reads (39%) | catalogued as rs1435167501; called by muse, mutect2, varscan2
- CXCR4 | c.15+398G>A | Intron (SNP) | VAF 80/208 reads (38%) | catalogued as rs191111700, COSV54016653; called by muse, mutect2, varscan2
- LPP-AS2 | n.1784A>G | RNA (SNP) | VAF 185/431 reads (43%) | called by muse, mutect2, varscan2
- MYC | c.-84C>T | 5'UTR (SNP) | VAF 44/135 reads (33%) | catalogued as COSV52370133, COSV52378515; called by muse, mutect2
